Somatic mutation profile of tumor specimen TARGET-10-PAPDSW-09A (aliquot TARGET-10-PAPDSW-09A-01D) from TARGET case TARGET-10-PAPDSW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,306 days).
Specimen TARGET-10-PAPDSW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76af3fbe-a468-44e7-938e-0b44a095fa61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDSW-10A (Blood Derived Normal), aliquot TARGET-10-PAPDSW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cb64c7b-ad57-4dab-82bc-d0adfab09940

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Intron 2, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- FSIP2 | c.19702G>A p.E6568K | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100555057; called by muse, mutect2, varscan2
- GDE1 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 36/54 reads (67%) | catalogued as rs1567340863; called by muse, mutect2, varscan2
- IL25 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs767430645, COSV59306825; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ODF4 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs148593560; called by muse, mutect2, varscan2
- R3HCC1L | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV54401301; called by muse, mutect2, varscan2
- HIVEP1 | c.7099_7100insGGTCTC p.T2366_L2367insRS | In Frame Ins (INS) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- KIF5A | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- KIF5A | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ZNF143 | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- NOX4 | c.810T>C p.C270= | Silent (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- UBR1 | c.4812C>A p.L1604= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- ADGRE2 | c.355+50T>C | Intron (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- PON3 | c.777+100G>A | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2
